Somatic mutation profile of tumor specimen TARGET-10-PASTDU-09A (aliquot TARGET-10-PASTDU-09A-01D) from TARGET case TARGET-10-PASTDU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.9 years (3,236 days).
Specimen TARGET-10-PASTDU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc3f37f6-cb28-45dc-a46c-9b1d0684bbee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASTDU-10A (Blood Derived Normal), aliquot TARGET-10-PASTDU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22f92320-9481-42d2-a572-015ea0fb4d6a

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Splice Site 3, Intron 2, Nonsense Mutation 2, Frame Shift Ins 2, In Frame Ins 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 19/46 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACOT12 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs113234186, COSV56892781; called by muse, mutect2, varscan2
- CACNA1H | c.1870G>A p.G624S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs750987846, COSV61984459; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPE | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs138641684; called by muse, mutect2, varscan2
- CTNND2 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 38/72 reads (53%) | catalogued as rs1027521829, COSV58867697; called by muse, mutect2, varscan2
- EPHA6 | c.3075C>A p.D1025E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV67560473; called by mutect2, varscan2
- HAPLN3 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372290878; called by muse, mutect2
- MMADHC | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.11); catalogued as COSV57573145; called by muse, mutect2, varscan2
- NOTCH1 | c.5126T>C p.L1709P | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.765); catalogued as rs886043624, COSV53025282; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHF6 | c.834+1G>C p.X278_splice (on ENST00000332070 / NM_032458.3; = p.V280L on NM_032335.3) | Splice Site (SNP) | VAF 21/21 reads (100%) | catalogued as COSV59699694, COSV59699754; called by muse, mutect2, varscan2
- SPTB | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs1009915997, COSV67629973; called by muse, mutect2, varscan2
- TCF7 | c.402_403insA p.S135Ifs*57 | Frame Shift Ins (INS) | VAF 26/53 reads (49%) | catalogued as COSV100389946, COSV58655683; called by mutect2, pindel, varscan2
- THEMIS | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs1403938167, COSV64069387; called by muse, mutect2, varscan2
- VSTM2B | c.297+2dup p.X99_splice | Splice Site (INS) | VAF 14/34 reads (41%) | catalogued as rs1224811955; called by mutect2, pindel, varscan2
- WT1 | c.471_472insAACCAAACCTGAT p.E158Nfs*4 | Nonsense Mutation (INS) | VAF 12/22 reads (55%) | catalogued as COSV60066846; called by mutect2, varscan2
- AKT2 | c.246_247insAGAAAACCCACA p.T82_V83insRKPT | In Frame Ins (INS) | VAF 31/78 reads (40%) | called by mutect2, pindel, varscan2
- CMTM1 | c.470_471insTGA p.Y157_P158insD (on ENST00000457188 / NM_181269.3; = p.Y274_P275insD on NM_052999.4) | In Frame Ins (INS) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- FOLH1B | n.1190+2T>A | Splice Site (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- MGA | c.1245_1246insTA p.N416* | Frame Shift Ins (INS) | VAF 44/104 reads (42%) | called by mutect2, pindel, varscan2
- GJD4 | c.423C>T p.A141= | Silent (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- LRBA | c.8463C>T p.D2821= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs766472618, COSV100840842; called by muse, mutect2, varscan2
- SBNO1 | c.1338T>C p.P446= (on ENST00000420886; = p.P445= on NM_018183.5) | Silent (SNP) | VAF 14/20 reads (70%) | called by muse, mutect2
- WFS1 | c.933C>A p.G311= | Silent (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- DLG4 | chr17:7219778 G>A | 5'Flank (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- KLF6 | c.676+15G>A | Intron (SNP) | VAF 8/39 reads (21%) | catalogued as rs774471588; called by muse, mutect2, varscan2
- STAB1 | c.2347+20G>A | Intron (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
